Somatic mutation profile of tumor specimen ALCH-AETD-TTP1-A (aliquot ALCH-AETD-TTP1-A-2-0-D-A673-36) from ALCHEMIST case ALCH-AETD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 46.2 years (16,866 days).
Specimen ALCH-AETD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0421e170-9720-4917-94ac-122255c209a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AETD-NB1-A (Blood Derived Normal), aliquot ALCH-AETD-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63366e47-9f77-4739-8326-8d27895bfa02

The open-access MAF lists 337 somatic variants for this specimen: 230 protein-altering or splice-affecting, 70 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 205, Silent 70, Nonsense Mutation 17, Intron 13, RNA 11, 3'UTR 9, Frame Shift Del 3, Splice Site 3, Splice Region 2, 5'Flank 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 33/494 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 10/204 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2
- ADGRG6 | c.2167G>T p.V723L | Missense Mutation (SNP) | VAF 20/452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1378795901, COSV51588232; called by muse, mutect2
- ALDOA | c.1206G>T p.Q402H (on ENST00000642816 / NM_001243177.4; = p.Q348H on NM_184041.5) | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1567326458; called by muse, mutect2
- ANO5 | c.345G>T p.L115F | Missense Mutation (SNP) | VAF 22/536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CS140510, COSV61091163; called by muse, mutect2
- ARHGEF28 | c.1699G>A p.G567R | Missense Mutation (SNP) | VAF 27/563 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV55247803; called by muse, mutect2
- ATP8A1 | c.1003G>C p.G335R | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.102); catalogued as COSV52538384; called by muse, mutect2
- BBS12 | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 29/479 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1560706525; called by muse, mutect2
- CCDC114 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59558974; called by muse, mutect2
- CFL1 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100354147; called by muse, mutect2
- CLRN2 | c.553T>C p.Y185H | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs944101777; called by muse, mutect2
- CNTNAP4 | c.3535C>G p.L1179V | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as rs1317601157; called by muse, mutect2
- CPVL | c.442A>G p.M148V | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.096); catalogued as rs1356835449; called by muse, mutect2
- CSMD3 | c.3861T>A p.H1287Q (on ENST00000297405 / NM_001363185.1; = p.H1183Q on NM_052900.3) | Missense Mutation (SNP) | VAF 24/456 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV99843994; called by muse, mutect2
- DCAF12L1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64421589; called by muse, mutect2
- DCC | c.1644G>T p.W548C | Missense Mutation (SNP) | VAF 30/670 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59135201; called by muse, mutect2
- DDC | c.1243G>C p.G415R | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs752006634; called by muse, mutect2
- DOCK11 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779410439; called by muse, mutect2
- FAM71E1 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1256127347; called by muse, mutect2
- KCNJ1 | c.58A>G p.M20V | Missense Mutation (SNP) | VAF 23/407 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs1472426789; called by muse, mutect2
- KIR2DL1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 13/344 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as COSV52410457; called by muse, mutect2
- KNG1 | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV53981077, COSV53981149; called by muse, mutect2
- LAMA2 | c.2957G>A p.W986* | Nonsense Mutation (SNP) | VAF 20/661 reads (3%) | catalogued as COSV70357241; called by muse, mutect2
- MRGPRD | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV58422847; called by muse, mutect2
- MS4A14 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55734035; called by muse, mutect2
- MUC2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs907029763; called by muse, mutect2, varscan2
- NECAP1 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100331568; called by muse, mutect2
- OR2H1 | c.252G>T p.W84C | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as COSV65810203; called by muse, mutect2
- OR52K2 | c.814C>A p.P272T | Missense Mutation (SNP) | VAF 19/350 reads (5%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.527); catalogued as COSV100355638; called by muse, mutect2
- PARG | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554832457; called by muse, mutect2
- PCDH17 | c.120G>C p.R40S | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV64974268; called by muse, mutect2
- PCDHA4 | c.1285G>T p.D429Y | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100793455, COSV63543359; called by muse, mutect2
- PCNX2 | c.2993C>T p.S998L | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs775337185, COSV50790073; called by muse, mutect2
- PEBP4 | c.368T>A p.L123Q | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV99835687; called by muse, mutect2
- PFKL | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1052017878; called by muse, varscan2
- PHKA2 | c.2896G>T p.V966F | Missense Mutation (SNP) | VAF 30/479 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66053350; called by muse, mutect2
- PREX2 | c.2987C>T p.A996V | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs779206847; called by muse, mutect2
- PRR23B | c.746C>A p.P249Q | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as COSV61493304; called by muse, mutect2
- PXDNL | c.3862C>A p.P1288T | Missense Mutation (SNP) | VAF 17/263 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV62485474; called by muse, mutect2
- RNMT | c.975-1G>T p.X325_splice | Splice Site (SNP) | VAF 20/375 reads (5%) | catalogued as COSV100054577; called by muse, mutect2
- SIPA1L2 | c.1880A>G p.N627S | Missense Mutation (SNP) | VAF 25/304 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV53383962, COSV53401947; called by muse, mutect2
- SMARCA4 | c.4090G>T p.E1364* | Nonsense Mutation (SNP) | VAF 21/216 reads (10%) | catalogued as COSV100759140, COSV60796160; called by muse, mutect2
- SPHKAP | c.4820G>C p.S1607T (on ENST00000392056 / NM_001142644.2; = p.S1578T on NM_030623.3) | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV60878714; called by muse, mutect2
- SVIL | c.2310del p.T771Lfs*2 | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | catalogued as COSV63443821; called by mutect2, varscan2
- TENM1 | c.6488C>T p.S2163F | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV100950510, COSV64438218; called by muse, mutect2
- TFAP2D | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV50411564; called by muse, mutect2
- TRIML2 | c.252G>T p.L84F | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV58714877; called by muse, mutect2
- TRPC3 | c.518C>A p.A173E (on ENST00000379645 / NM_001366479.2; = p.A100E on NM_003305.2) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as rs141601839, COSV53378851; called by mutect2, varscan2
- YBX3 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 13/271 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.77); catalogued as rs976522004; called by muse, mutect2
- ZEB2 | c.1540C>A p.P514T | Missense Mutation (SNP) | VAF 17/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181298165; called by muse, mutect2
- ZFHX4 | c.7055C>G p.S2352C | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs763192128, COSV50558125; called by muse, mutect2
- ZNF716 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 17/293 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); catalogued as COSV70779837; called by muse, mutect2
- ZNF770 | c.929A>G p.N310S | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1425263029; called by muse, mutect2
- ZNF804A | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 10/238 reads (4%) | catalogued as COSV56467533; called by muse, mutect2
- ABCB7 | c.397A>T p.R133W (on ENST00000373394 / NM_001271696.3; = p.R134W on NM_004299.6) | Missense Mutation (SNP) | VAF 26/542 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2
- ABCC8 | c.2801A>G p.Q934R | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2
- ABHD10 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 16/389 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAM7 | c.848A>T p.K283M | Missense Mutation (SNP) | VAF 20/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ADAMTS6 | c.2413A>T p.T805S | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ADCY9 | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- ADGB | c.4424G>T p.W1475L | Missense Mutation (SNP) | VAF 26/660 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- ADH1A | c.984T>A p.C328* | Nonsense Mutation (SNP) | VAF 18/397 reads (5%) | called by muse, mutect2
- AKR1B15 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- AMPD1 | c.1488-7C>G | Splice Region (SNP) | VAF 20/490 reads (4%) | called by muse, mutect2
- ANK2 | c.5207C>A p.S1736* | Nonsense Mutation (SNP) | VAF 15/257 reads (6%) | called by muse, mutect2
- ANKFN1 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); called by muse, mutect2
- ARMH4 | c.430A>T p.M144L | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2
- ARSH | c.1430A>G p.H477R | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ASB12 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP11C | c.1499A>T p.D500V | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP7A | c.67G>C p.V23L | Missense Mutation (SNP) | VAF 26/564 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- AURKC | c.163G>T p.G55W (on ENST00000302804 / NM_001015878.2; = p.G21W on NM_003160.3) | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C16orf71 | c.335C>A p.T112K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- C18orf63 | c.1391C>A p.T464K | Missense Mutation (SNP) | VAF 15/512 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); called by muse, mutect2
- C1orf105 | c.446C>G p.T149R | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- C2CD3 | c.4779G>T p.Q1593H | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); called by muse, mutect2
- C8orf34 | c.456G>T p.W152C | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CASK | c.354C>A p.A118= | Splice Region (SNP) | VAF 40/574 reads (7%) | called by muse, mutect2
- CCDC15 | c.2711G>T p.C904F | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CCDC168 | c.8111T>A p.V2704D | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.047); called by muse, mutect2
- CCNB3 | c.566T>A p.L189* | Nonsense Mutation (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- CD180 | c.542A>T p.Q181L | Missense Mutation (SNP) | VAF 19/329 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.588); called by muse, mutect2
- CDH11 | c.2109G>T p.M703I | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2
- CDH20 | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 29/563 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.024); called by muse, mutect2
- CER1 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.382); called by muse, mutect2
- CLCA1 | c.1750T>C p.S584P | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, mutect2
- CLCN5 | c.725T>G p.V242G | Missense Mutation (SNP) | VAF 28/504 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- COBL | c.2151G>T p.M717I | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.095); called by muse, mutect2
- COL15A1 | c.904C>A p.L302M | Missense Mutation (SNP) | VAF 17/269 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.077); called by muse, mutect2
- COL4A6 | c.4703G>T p.C1568F | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP2E1 | c.782G>C p.C261S | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.35); called by muse, mutect2
- DCC | c.1643G>T p.W548L | Missense Mutation (SNP) | VAF 30/669 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCTN6 | c.82A>G p.T28A | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.2); called by muse, mutect2
- DGKI | c.3181C>A p.L1061M | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.921); called by muse, mutect2
- DHX57 | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DMD | c.2644G>T p.D882Y | Missense Mutation (SNP) | VAF 40/544 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.269); called by muse, mutect2
- DNAH8 | c.11689C>G p.L3897V | Missense Mutation (SNP) | VAF 19/467 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); called by muse, mutect2
- DNAJC21 | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 44/578 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DSG3 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- DSG3 | c.2065G>T p.V689L | Missense Mutation (SNP) | VAF 34/462 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- DYNC2H1 | c.7040G>T p.R2347I | Missense Mutation (SNP) | VAF 23/708 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EOGT | c.163A>T p.R55W | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.267); called by muse, mutect2
- ETAA1 | c.605T>G p.M202R | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- FANCB | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); called by muse, mutect2
- FAT4 | c.3052G>T p.V1018L | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.976); called by muse, mutect2
- FLG | c.11089C>A p.R3697S | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- FLT3 | c.1291T>A p.F431I | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.25); called by muse, mutect2
- FMN1 | c.4207G>C p.A1403P (on ENST00000616417 / NM_001277313.2; = p.A1180P on NM_001103184.4) | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2
- FRMPD3 | c.1801A>T p.S601C | Missense Mutation (SNP) | VAF 23/454 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2
- GBP6 | c.785A>G p.Q262R | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT tolerated (0.91); PolyPhen benign (0.009); called by muse, mutect2
- GCNT4 | c.339T>A p.Y113* | Nonsense Mutation (SNP) | VAF 12/332 reads (4%) | called by muse, mutect2
- GFAP | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.393); called by muse, mutect2
- GFPT1 | c.149G>T p.W50L | Missense Mutation (SNP) | VAF 26/547 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.062); called by muse, mutect2
- GNL3L | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- GRIA1 | c.1768A>T p.S590C | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- GRIK5 | c.1346A>T p.D449V | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- HAS2 | c.1507C>A p.P503T | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- HOXA10 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HUWE1 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- IFT88 | c.665A>T p.Y222F (on ENST00000319980 / NM_001318493.2; = p.Y213F on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/470 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- IGHG3 | c.723G>T p.Q241H | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2
- IL1RAPL1 | c.378T>A p.C126* | Nonsense Mutation (SNP) | VAF 26/404 reads (6%) | called by muse, mutect2
- IQSEC3 | c.3032G>A p.G1011E (on ENST00000538872 / NM_001170738.2; = p.G708E on NM_015232.1) | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2
- KCND2 | c.109A>T p.R37W | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2
- KEL | c.1303A>T p.T435S | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.033); called by muse, mutect2
- KIR2DL3 | c.965G>C p.R322T | Missense Mutation (SNP) | VAF 24/507 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2
- KLHL13 | c.1606A>T p.R536W | Missense Mutation (SNP) | VAF 17/380 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- KLHL40 | c.986T>G p.V329G | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KLHL41 | c.1024A>G p.T342A | Missense Mutation (SNP) | VAF 18/321 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2
- KMO | c.69A>T p.Q23H | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.78); called by muse, mutect2
- LAMA2 | c.4100G>C p.G1367A | Missense Mutation (SNP) | VAF 23/561 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- LAMB1 | c.1242T>A p.Y414* | Nonsense Mutation (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- LGR4 | c.2453G>T p.R818L | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2
- LILRA4 | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2
- LYPD5 | c.643A>T p.R215W (on ENST00000377950 / NM_001031749.3; = p.R172W on NM_182573.2) | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2
- MAGEA6 | c.817T>A p.W273R | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEB6B | c.452C>G p.A151G | Missense Mutation (SNP) | VAF 15/323 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.552); called by muse, mutect2
- MARF1 | c.3347C>T p.S1116F | Missense Mutation (SNP) | VAF 32/516 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- MARK2 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- MFN1 | c.248+1G>T p.X83_splice | Splice Site (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- MFSD5 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MIDEAS | c.2447G>T p.R816L | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2
- MMP3 | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- MMRN1 | c.953C>A p.P318Q | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.691); called by muse, mutect2
- MOAP1 | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MRO | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- MRPL53 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.026); called by muse, mutect2
- MYH6 | c.1370T>A p.F457Y | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2
- MYO6 | c.1223+1G>T p.X408_splice | Splice Site (SNP) | VAF 20/446 reads (4%) | called by muse, mutect2
- MYT1 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.036); called by muse, mutect2
- NABP1 | c.218G>C p.R73P | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.153); called by muse, mutect2
- NDUFAB1 | c.227T>G p.L76* | Nonsense Mutation (SNP) | VAF 14/253 reads (6%) | called by muse, mutect2
- NIBAN1 | c.2427del p.M811Wfs*36 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, varscan2
- NOP53 | c.487del p.R163Gfs*26 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- NOS1 | c.1207G>C p.D403H | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2
- NRK | c.1955A>C p.N652T | Missense Mutation (SNP) | VAF 22/423 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2
- OR7G2 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 25/288 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.22); called by muse, mutect2
- OSTN | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- OTUD6A | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.717); called by muse, mutect2
- PCDHB11 | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 21/410 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB13 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 14/403 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- PDE11A | c.624G>C p.L208F | Missense Mutation (SNP) | VAF 35/722 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- PDLIM4 | c.859A>T p.N287Y | Missense Mutation (SNP) | VAF 15/313 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHC3 | c.1224G>T p.Q408H (on ENST00000494943 / NM_001308116.2; = p.Q420H on NM_024947.4) | Missense Mutation (SNP) | VAF 40/474 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2
- PHKB | c.2067A>T p.E689D | Missense Mutation (SNP) | VAF 50/568 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2
- PIK3R4 | c.2567A>T p.N856I | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- PITPNC1 | c.68A>G p.Y23C | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PKHD1L1 | c.6116C>A p.A2039E | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- PLCE1 | c.2485T>G p.S829A | Missense Mutation (SNP) | VAF 22/325 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2
- PP2D1 | c.1348C>A p.L450I | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.657); called by muse, mutect2
- PPFIBP1 | c.2839G>C p.D947H (on ENST00000318304 / NM_177444.3; = p.D941H on NM_003622.4) | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); called by muse, mutect2
- PPP1R9A | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- PPP4R2 | c.275C>G p.T92S | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.192); called by muse, mutect2
- PRAMEF14 | c.655C>A p.R219S | Missense Mutation (SNP) | VAF 26/560 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- PRKCG | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 15/386 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); called by muse, mutect2
- PRUNE2 | c.6142T>A p.F2048I | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2
- PSMG2 | c.548G>C p.G183A | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PXYLP1 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RBFOX1 | c.696G>C p.Q232H | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2
- RBMXL3 | c.1588C>A p.H530N | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.255); called by muse, mutect2
- RELN | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 28/555 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RFPL2 | c.679T>A p.S227T | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.173); called by muse, mutect2
- RFX7 | c.1717C>T p.P573S (on ENST00000559447 / NM_001368074.1; = p.P670S on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.027); called by muse, mutect2
- RGS9BP | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); called by muse, mutect2
- SAP130 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); called by muse, mutect2
- SATB2 | c.1791A>T p.R597S | Missense Mutation (SNP) | VAF 22/469 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.05); called by muse, mutect2
- SCN7A | c.2965G>T p.A989S | Missense Mutation (SNP) | VAF 23/471 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SKA1 | c.174G>C p.L58F | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); called by muse, mutect2
- SLC16A12 | c.829T>C p.F277L | Missense Mutation (SNP) | VAF 28/480 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.251); called by muse, mutect2
- SLC4A8 | c.2362A>T p.I788F | Missense Mutation (SNP) | VAF 18/341 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.139); called by muse, mutect2
- SMARCA2 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPART | c.1116G>T p.L372F | Missense Mutation (SNP) | VAF 33/622 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.216); called by muse, mutect2
- SPOPL | c.248A>T p.Y83F | Missense Mutation (SNP) | VAF 23/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRL | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 11/239 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SYNE1 | c.19652A>G p.Q6551R (on ENST00000367255 / NM_182961.4; = p.Q6480R on NM_033071.3) | Missense Mutation (SNP) | VAF 28/684 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.948); called by muse, mutect2
- TBC1D8B | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 21/376 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.072); called by muse, mutect2
- TBRG4 | c.1760G>T p.R587L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TENM2 | c.1257G>T p.R419S | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- TEX13C | c.2679G>T p.R893S | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.9); called by muse, mutect2
- TMEM132B | c.2504G>T p.G835V | Missense Mutation (SNP) | VAF 27/338 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2
- TMPRSS15 | c.1057T>A p.F353I | Missense Mutation (SNP) | VAF 26/554 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- TNKS1BP1 | c.4102G>T p.G1368C | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM48 | c.127A>T p.T43S | Missense Mutation (SNP) | VAF 33/546 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); called by muse, mutect2
- TRPC6 | c.2488G>T p.G830W | Missense Mutation (SNP) | VAF 51/580 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.237); called by muse, mutect2
- TRPM6 | c.5848G>T p.G1950* | Nonsense Mutation (SNP) | VAF 22/484 reads (5%) | called by muse, mutect2
- TSHZ2 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.997); called by muse, mutect2
- TSPAN32 | c.764C>A p.S255Y | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.601); called by muse, mutect2
- TTN | c.100871C>A p.S33624* (on ENST00000591111; = p.S26200* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 22/202 reads (11%) | called by muse, mutect2
- TTN | c.61692G>T p.R20564S (on ENST00000591111; = p.R13140S on NM_003319.4) | Missense Mutation (SNP) | VAF 10/270 reads (4%) | PolyPhen possibly damaging (0.52); called by muse, mutect2
- TXLNG | c.199C>A p.Q67K | Missense Mutation (SNP) | VAF 22/321 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.053); called by muse, mutect2
- UBA6 | c.818T>C p.I273T | Missense Mutation (SNP) | VAF 16/401 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2
- UBE2NL | c.336G>T p.L112F | Missense Mutation (SNP) | VAF 36/524 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2
- UBE3C | c.920G>T p.R307I | Missense Mutation (SNP) | VAF 14/349 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, mutect2
- UHRF1BP1L | c.3169G>T p.A1057S | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.034); called by muse, mutect2
- USF3 | c.1462G>T p.G488W | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- USP15 | c.150G>T p.W50C | Missense Mutation (SNP) | VAF 36/542 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USP51 | c.660G>T p.W220C | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2
- UTP14A | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.09); called by muse, mutect2
- VPS13C | c.6215C>T p.P2072L (on ENST00000644861 / NM_020821.3; = p.P2029L on NM_017684.5) | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- WDR75 | c.36T>G p.C12W | Missense Mutation (SNP) | VAF 31/526 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); called by muse, mutect2
- WNT9B | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- XIRP2 | c.131T>A p.L44H | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- XKR3 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 24/324 reads (7%) | called by muse, mutect2
- XRN1 | c.2587G>T p.G863* | Nonsense Mutation (SNP) | VAF 34/496 reads (7%) | called by muse, mutect2
- ZAN | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.622); called by muse, mutect2
- ZAN | c.3356G>C p.C1119S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF566 | c.840G>C p.E280D | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2
- ZNF717 | c.1839C>A p.H613Q | Missense Mutation (SNP) | VAF 18/411 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- ZNF880 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 16/229 reads (7%) | called by muse, mutect2
- ZSCAN25 | c.290A>C p.E97A | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ABCC8 | c.894C>T p.R298= | Silent (SNP) | VAF 13/132 reads (10%) | called by muse, mutect2
- ADGB | c.3645C>A p.P1215= | Silent (SNP) | VAF 13/288 reads (5%) | called by muse, mutect2
- APOB | c.2796A>T p.P932= | Silent (SNP) | VAF 11/200 reads (6%) | called by muse, mutect2
- ARR3 | c.555C>A p.R185= | Silent (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- BCHE | c.1167G>T p.V389= | Silent (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- BOD1L1 | c.4779G>T p.G1593= | Silent (SNP) | VAF 29/430 reads (7%) | called by muse, mutect2
- C1orf127 | c.2097G>T p.L699= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- CCNB3 | c.564C>A p.S188= | Silent (SNP) | VAF 10/229 reads (4%) | catalogued as COSV99329710; called by muse, mutect2
- CD207 | c.186C>A p.V62= | Silent (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- CENPF | c.7176A>T p.S2392= | Silent (SNP) | VAF 13/279 reads (5%) | called by muse, mutect2
- CEP170 | c.3726A>G p.E1242= | Silent (SNP) | VAF 16/316 reads (5%) | called by muse, mutect2
- CFH | c.1533C>T p.I511= | Silent (SNP) | VAF 18/369 reads (5%) | catalogued as COSV100809983, COSV66410847; called by muse, mutect2
- CPS1 | c.6G>T p.T2= | Silent (SNP) | VAF 24/334 reads (7%) | called by muse, mutect2
- CSMD3 | c.10623T>G p.L3541= (on ENST00000297405 / NM_001363185.1; = p.L3372= on NM_052900.3) | Silent (SNP) | VAF 22/502 reads (4%) | called by muse, mutect2
- DGKK | c.2997C>A p.T999= | Silent (SNP) | VAF 20/282 reads (7%) | catalogued as rs1557224052; called by muse, mutect2
- DLG5 | c.2547G>T p.T849= | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- DOCK11 | c.4167C>T p.D1389= | Silent (SNP) | VAF 33/602 reads (5%) | called by muse, mutect2
- EFHC2 | c.2010G>A p.L670= | Silent (SNP) | VAF 28/394 reads (7%) | called by muse, mutect2
- EFR3B | c.1758C>T p.V586= | Silent (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- EPS8 | c.1800A>G p.P600= | Silent (SNP) | VAF 17/302 reads (6%) | called by muse, mutect2
- FAM135A | c.4320A>T p.T1440= (on ENST00000370479 / NM_001351599.1; = p.T1227= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/266 reads (6%) | called by muse, mutect2
- FAT1 | c.3804G>C p.R1268= | Silent (SNP) | VAF 28/468 reads (6%) | called by muse, mutect2
- FAT4 | c.13164C>A p.S4388= | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- FLNB | c.1449A>G p.G483= | Silent (SNP) | VAF 36/475 reads (8%) | called by muse, mutect2
- FSIP2 | c.2823C>A p.I941= | Silent (SNP) | VAF 14/412 reads (3%) | called by muse, mutect2
- GAB4 | c.1113T>A p.A371= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- H2AC17 | c.198G>T p.L66= | Silent (SNP) | VAF 14/196 reads (7%) | called by muse, mutect2
- HINT1 | c.153T>C p.H51= | Silent (SNP) | VAF 11/217 reads (5%) | called by muse, mutect2
- HSPD1 | c.696A>G p.S232= | Silent (SNP) | VAF 18/338 reads (5%) | called by muse, mutect2
- IRAG2 | c.4179T>C p.N1393= (on ENST00000636465; = p.N438= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- KCNJ16 | c.195T>C p.L65= | Silent (SNP) | VAF 20/434 reads (5%) | called by muse, mutect2
- KCNJ4 | c.423C>T p.C141= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs370163973, COSV99068318; called by mutect2, varscan2
- KCNK4 | c.75G>T p.R25= | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- KRT10 | c.1386C>G p.G462= | Silent (SNP) | VAF 10/246 reads (4%) | catalogued as COSV99510291; called by muse, mutect2
- KRT2 | c.1896C>A p.S632= | Silent (SNP) | VAF 10/211 reads (5%) | called by muse, mutect2
- LAMB4 | c.699C>A p.L233= | Silent (SNP) | VAF 30/346 reads (9%) | called by muse, mutect2
- LOXHD1 | c.2770C>A p.R924= | Silent (SNP) | VAF 31/404 reads (8%) | called by muse, mutect2
- LPAR4 | c.1098A>G p.L366= | Silent (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- LRRC53 | c.675T>A p.L225= | Silent (SNP) | VAF 22/276 reads (8%) | called by muse, mutect2
- MCM8 | c.2121A>C p.P707= | Silent (SNP) | VAF 15/306 reads (5%) | called by muse, mutect2
- MDN1 | c.1639C>T p.L547= | Silent (SNP) | VAF 11/236 reads (5%) | catalogued as rs1349685051, COSV99054802; called by muse, mutect2
- MYLK | c.4689C>A p.I1563= | Silent (SNP) | VAF 27/486 reads (6%) | catalogued as COSV60621045; called by muse, mutect2
- MYO7A | c.6388C>T p.L2130= | Silent (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- NEO1 | c.4200C>G p.A1400= | Silent (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- NLGN4X | c.1653C>G p.P551= | Silent (SNP) | VAF 24/486 reads (5%) | called by muse, mutect2
- NUTM1 | c.498T>G p.V166= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- OR5M8 | c.150C>T p.A50= | Silent (SNP) | VAF 9/229 reads (4%) | called by muse, mutect2
- OTOGL | c.3876T>C p.L1292= (on ENST00000547103; = p.L1283= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/292 reads (6%) | called by muse, mutect2
- PPM1B | c.1299T>G p.A433= | Silent (SNP) | VAF 38/498 reads (8%) | called by muse, mutect2
- PPP6R2 | c.132G>T p.L44= | Silent (SNP) | VAF 10/252 reads (4%) | catalogued as COSV53296291; called by muse, mutect2
- PPRC1 | c.2197C>T p.L733= | Silent (SNP) | VAF 13/230 reads (6%) | called by muse, mutect2
- PRKG2 | c.336G>A p.L112= | Silent (SNP) | VAF 18/483 reads (4%) | called by muse, mutect2
- RYR1 | c.3771C>A p.S1257= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV62107687; called by muse, mutect2
- SCN2A | c.1651A>C p.R551= | Silent (SNP) | VAF 22/360 reads (6%) | called by muse, mutect2
- SEC62 | c.771A>G p.G257= | Silent (SNP) | VAF 11/204 reads (5%) | called by muse, mutect2
- SEMA4C | c.2019G>T p.G673= | Silent (SNP) | VAF 4/45 reads (9%) | called by mutect2, varscan2
- SEMA5A | c.1905G>T p.V635= | Silent (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2
- SP7 | c.183G>T p.G61= | Silent (SNP) | VAF 54/562 reads (10%) | called by muse, mutect2
- STK4 | c.1002G>A p.V334= | Silent (SNP) | VAF 8/149 reads (5%) | called by muse, mutect2
- SUPT20H | c.660C>T p.N220= (on ENST00000350612 / NM_001014286.3; = p.N221= on NM_017569.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/321 reads (4%) | called by muse, mutect2
- SYNE1 | c.2298T>A p.I766= (on ENST00000367255 / NM_182961.4; = p.I773= on NM_033071.3) | Silent (SNP) | VAF 18/512 reads (4%) | called by muse, mutect2
- TFAM | c.33G>T p.L11= | Silent (SNP) | VAF 18/410 reads (4%) | called by muse, mutect2
- TRIT1 | c.270G>T p.V90= | Silent (SNP) | VAF 11/210 reads (5%) | called by muse, mutect2
- TTN | c.45972T>A p.I15324= (on ENST00000591111; = p.I7900= on NM_003319.4) | Silent (SNP) | VAF 29/495 reads (6%) | called by muse, mutect2
- WDR64 | c.2496T>A p.A832= | Silent (SNP) | VAF 26/272 reads (10%) | called by muse, mutect2
- WNK3 | c.2442C>A p.A814= | Silent (SNP) | VAF 18/323 reads (6%) | called by muse, mutect2
- ZGPAT | c.1515G>A p.L505= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as rs1294947966; called by muse, mutect2
- ZNF256 | c.450G>C p.G150= | Silent (SNP) | VAF 22/540 reads (4%) | called by muse, mutect2
- ZNF804A | c.945A>G p.Q315= | Silent (SNP) | VAF 13/157 reads (8%) | catalogued as COSV56446009; called by muse, mutect2
- ZNF804B | c.3264A>T p.S1088= | Silent (SNP) | VAF 19/188 reads (10%) | called by muse, mutect2, varscan2
- AC114741.1 | n.422G>T | RNA (SNP) | VAF 32/406 reads (8%) | called by muse, mutect2
- ACSF3 | c.*1227A>T | 3'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, varscan2
- AGXT | c.*8A>T | 3'UTR (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- AL359195.2 | n.3720C>G | RNA (SNP) | VAF 12/274 reads (4%) | called by muse, mutect2
- ATPSCKMT | c.307-318A>T | Intron (SNP) | VAF 38/255 reads (15%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+3533G>T | Intron (SNP) | VAF 30/566 reads (5%) | called by muse, mutect2
- C11orf1 | c.46-839C>T | Intron (SNP) | VAF 26/392 reads (7%) | called by muse, mutect2
- CALCA | c.*19T>A | 3'UTR (SNP) | VAF 26/409 reads (6%) | called by muse, mutect2
- CAMK2B | c.415-1483C>A | Intron (SNP) | VAF 6/49 reads (12%) | called by mutect2, varscan2
- CDIPT | chr16:29864307 G>C | 5'Flank (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- CHCHD2P9 | n.414T>A | RNA (SNP) | VAF 15/192 reads (8%) | called by muse, mutect2
- ERICH1 | c.1258+75G>T | Intron (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- FMR1 | c.*547C>A | 3'UTR (SNP) | VAF 28/753 reads (4%) | called by muse, mutect2
- FOXP2 | c.*3634A>G | 3'UTR (SNP) | VAF 15/229 reads (7%) | called by muse, mutect2
- GLT1D1 | c.68+10500T>C | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as rs1468416707; called by muse, mutect2
- GOLGA6L17P | n.221A>C | RNA (SNP) | VAF 20/398 reads (5%) | called by muse, mutect2
- GPM6B | c.61+9167G>T | Intron (SNP) | VAF 8/106 reads (8%) | catalogued as rs1316957370; called by muse, mutect2
- HDDC3 | c.409+131G>T | Intron (SNP) | VAF 20/432 reads (5%) | called by muse, mutect2
- LINC01517 | n.657G>C | RNA (SNP) | VAF 13/195 reads (7%) | catalogued as rs1223771606; called by muse, mutect2
- LINC01559 | n.306A>C | RNA (SNP) | VAF 11/196 reads (6%) | called by muse, mutect2
- LYNX1-SLURP2 | c.*195G>T | 3'UTR (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- MIR508 | n.18T>C | RNA (SNP) | VAF 10/252 reads (4%) | called by muse, mutect2
- OFCC1 | n.314G>T | RNA (SNP) | VAF 20/356 reads (6%) | called by muse, mutect2
- OR56B3P | n.647C>A | RNA (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- PDE1A | c.*21G>T | 3'UTR (SNP) | VAF 20/247 reads (8%) | called by muse, mutect2
- PRR16 | c.159+16572G>T | Intron (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2, varscan2
- RALGPS2 | c.1040+13A>G | Intron (SNP) | VAF 14/217 reads (6%) | called by muse, mutect2
- SEC24D | c.397+436A>T | Intron (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- SMPX | c.*197C>A | 3'UTR (SNP) | VAF 20/358 reads (6%) | catalogued as rs1307318857; called by muse, mutect2
- SNRPN | chr15:24980069 G>T | 3'Flank (SNP) | VAF 15/272 reads (6%) | called by muse, mutect2
- SSH1 | c.111-2755G>T | Intron (SNP) | VAF 28/427 reads (7%) | called by muse, mutect2
- STX5 | c.-66G>A | 5'UTR (SNP) | VAF 8/230 reads (3%) | catalogued as rs1193386520; called by muse, mutect2
- SULF1 | c.*706G>T | 3'UTR (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- TTC3P1 | n.4926C>T | RNA (SNP) | VAF 14/276 reads (5%) | called by muse, mutect2
- TTC3P1 | n.4925C>A | RNA (SNP) | VAF 14/278 reads (5%) | called by muse, mutect2
- TTN | c.10303+1374A>G | Intron (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- ZNFX1 | chr20:49278977 G>C | 5'Flank (SNP) | VAF 33/434 reads (8%) | called by muse, mutect2
